Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A45Q, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A45Q-01A (Primary Tumor).

[page 1 of 2]
1. Diagnosis Discrepancy		☒
2. Primary Tumor Site Discrepancy		☒
3. HIPAA Discrepancy		☒
4. Prior Malignancy History		☒
5. Dual/Synchronous Primary Malignancy		☒
7. Reviewer Initials: RS	Date Reviewed: 8/24/12	

DOB:

Sex: F

Physician:

Received

Pathologist:

Accession:

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to , the section "SPECIMEN" may have been added. ****

SUPPLEMENTAL REPORT

CONSULTANT:
TIME RECD:
PHOTO: NO
DX COMPLETED:

TO

ICD-0-3
Carcinoma, squamous cell, NOS 8070/3
Site: oral cavity C06.9

hw
10/1/12

D:N

SUPPLEMENTAL REPORT

DIAGNOSIS :

(K) LEFT CLAVICLE:

Bone, no tumor present.

COMMENT: The portion of mandibular bone from specimen A shows squamous carcinoma invading the bone, present 5.0 mm from the anterior bony resection margin.

SECTION CODE: A21, representative section of tumor and mandible; A22-A29, anterior margin, perpendicular sections; K, representative section of clavicle.

DIAGNOSIS

- (A) LEFT RADICAL NECK DISSECTION, LEFT HEMIMANDIBULECTOMY:
SQUAMOUS CARCINOMA, WELL DIFFERENTIATED, OF BUCCAL MUCOSA EXTENDING INTO SUBMANDIBULAR GLAND AND SUBMANDIBULAR SOFT TISSUE.
Margins of resection free of tumor.
No evidence of vascular invasion.
METASTATIC SQUAMOUS CARCINOMA IN 1 OF 20 CERVICAL LYMPH NODES (0/1 SUBDIGASTRIC, 0/8 MIDJUGULAR, 0/1 LOWER JUGULAR, 1/4 UPPER POSTERIOR CERVICAL, 0/5 MIDPOSTERIOR CERVICAL, 0/1 LOWER POSTERIOR CERVICAL). (SEE COMMENT)
- (B) MEDIAL MUCOSAL MARGIN:
Squamous mucosa and soft tissue, no tumor present.
- (C) DISTAL MUCOSAL MARGIN:
Squamous mucosa with pseudoepitheliomatous hyperplasia, no tumor present.
- (D) LATERAL MUCOSAL MARGIN:
Squamous mucosa and soft tissue, no tumor present.
- (E) PROXIMAL MUCOSAL MARGIN:
Squamous mucosa with pseudoepitheliomatous hyperplasia, no tumor present.
- (F) PTERYGOID MUSCLE:
Skeletal muscle, no tumor present.
- (G) MYOHYOID MUSCLE:
Skeletal muscle, no tumor present.
- (H) BUCCAL FAT:
Skeletal muscle and fibroadipose tissue, no tumor present.

[page 2 of 2]
DOB:
Physician:

Sex: F

Received:

Pathologist:

Accession:

Case type: Surgical History

- (I) MASSETER MUSCLE:
Skeletal muscle and fibroconnective tissue, no tumor present.
- (J) SOFT TISSUE FROM INFERIOR ALVEOLAR CANAL:
Bone, no tumor present.
- (K) LEFT CLAVICLE:
Pending decalcification. (see comment)
- (L) TEETH:
Multiple teeth with enamel caps, gross examination only.

COMMENT

The portion of mandibular bone from specimen A and K, left clavicle are both submitted to the Bone Lab for decalcification and sectioning. An addendum report will be issued. The lymph node containing metastatic tumor is 2.0 cm in greatest dimension with a 0.1 cm focus of metastatic tumor and no extranodal extension.

SPECIMEN

- (A) LEFT RADICAL NECK DISSECTION, LEFT HEMIMANDIBULECTOMY:
- (B) MEDIAL MUCOSAL MARGIN:
- (C) DISTAL MUCOSAL MARGIN:
- (D) LATERAL MUCOSAL MARGIN:
- (E) PROXIMAL MUCOSAL MARGIN:
- (F) PTERYGOID MUSCLE:
- (G) MYOHYOID MUSCLE:
- (H) BUCCAL FAT:
- (I) MASSETER MUSCLE:
- (J) SOFT TISSUE FROM INFERIOR ALVEOLAR CANAL:
- (K) LEFT CLAVICLE:
- (L) TEETH:

SNOMED CODES

T-51300,M-80703

Source: NCI Genomic Data Commons file e051bdce-5132-46e8-a8be-ddf5d40ca34f (TCGA-CV-A45Q.5CBF6209-2CF3-4444-B2F1-C307394C0187.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).